CPTAC case C3N-00512 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/95d0e985-cdb7-4a85-a82d-60e008ce7be1

Demographics
Sex at birth: male; Race: white; Year of birth: 1974; Vital status: Dead; Days to death: 1,006 days (2.8 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 42.6 years (15,559 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 1,006 days (2.8 years); Days to last follow up: 1,006 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.8 cm (a second GDC size field records 2.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 10; Lymph nodes tested: 26; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (4 entries)
- Days to follow up: 426 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 710 days (1.9 years); Disease response: Progressive Disease; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 908 days (2.5 years); Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 1,006 days (2.8 years); Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 95 kg; Height: 184 cm; BMI: 28.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 24; Cigarettes per day: 20; Tobacco smoking onset year: 1992; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 30.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00512-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 159 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00512-21: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3N-00512-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 176 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00512-22: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 0.
- Sample C3N-00512-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 294 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00512-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
